Somatic mutation profile of tumor specimen TCGA-WC-A87W-01A (aliquot TCGA-WC-A87W-01A-11D-A39W-08) from TCGA case TCGA-WC-A87W, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.1 years (20,872 days).
Specimen TCGA-WC-A87W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45eed671-483d-4b58-81b4-ba63025d00a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A87W-10A (Blood Derived Normal), aliquot TCGA-WC-A87W-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8f7e8ee-d0e5-4492-9c79-9e584a0d8af3

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NBEAL2 | c.1031A>T p.K344M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs903364181; called by muse, mutect2, varscan2
- TRPM7 | c.5022A>T p.E1674D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1230531821; called by muse, mutect2, varscan2
- KIAA1549 | c.4819G>A p.V1607I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PPP1R15A | c.1192dup p.E398Gfs*6 | Frame Shift Ins (INS) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- PTPRG | c.82_85+9del p.X28_splice | Splice Site (DEL) | VAF 16/156 reads (10%) | called by mutect2, pindel
- SCN11A | c.2212C>A p.P738T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, varscan2
- IGSF11 | c.15A>G p.E5= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- MAGED1 | c.1581A>G p.Q527= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- RNF213 | c.10884C>T p.V3628= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
